Somatic mutation profile of tumor specimen TCGA-BQ-5888-01A (aliquot TCGA-BQ-5888-01A-11D-1589-08) from TCGA case TCGA-BQ-5888, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 74.9 years (27,346 days).
Specimen TCGA-BQ-5888-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc4c0923-9183-43b6-8e4f-d9129220affc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5888-11A (Solid Tissue Normal), aliquot TCGA-BQ-5888-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18e170ab-b2c2-4fa6-9598-58a8c4ae176b

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMIGO3 | c.1394A>G p.N465S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs770472787, COSV57538738; called by muse, mutect2, varscan2
- CAMK1D | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66611277, COSV66611886; called by muse, mutect2, varscan2
- CFH | c.2483A>T p.N828I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66408899; called by muse, mutect2, varscan2
- DIS3L2 | c.1195C>G p.L399V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56054980; called by muse, mutect2, varscan2
- GTSE1 | c.1861A>C p.K621Q | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.09); catalogued as COSV71889125; called by muse, mutect2, varscan2
- HNRNPL | c.541C>G p.R181G | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV55492837, COSV55495574; called by muse, mutect2, varscan2
- KHDRBS1 | c.1319A>G p.Y440C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV56982147, COSV56982378; called by muse, mutect2, varscan2
- KRTAP10-3 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.73); catalogued as rs369545090; called by muse, mutect2, varscan2
- MTBP | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.173); catalogued as COSV59963245; called by muse, mutect2
- OR5T2 | c.522C>A p.S174R | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV57589406; called by muse, mutect2, varscan2
- PPP1R15B | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 54/240 reads (23%) | catalogued as COSV65815821; called by muse, mutect2, varscan2
- TPCN1 | c.414+1G>T p.X138_splice | Splice Site (SNP) | VAF 72/380 reads (19%) | catalogued as COSV59235595; called by muse, varscan2
- TTLL7 | c.2536A>G p.N846D | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53084728; called by muse, mutect2, varscan2
- LILRB3 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYRF | c.1648_1654del p.V550Tfs*53 (on ENST00000278836 / NM_001127392.3; = p.V541Tfs*53 on NM_013279.4) | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.7458C>T p.L2486= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs569755271, COSV56361845; called by muse, mutect2, varscan2
- PRTN3 | c.40C>T p.L14= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV52255615; called by muse, mutect2, varscan2
- PTPRM | c.3654G>A p.R1218= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs771862211, COSV59860834; called by muse, mutect2, varscan2
- PTPRZ1 | c.5778G>A p.V1926= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV66437347; called by muse, mutect2, varscan2
- SLFN11 | c.2301C>T p.A767= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs377363363; called by muse, mutect2, varscan2
- TRPM4 | c.2769G>T p.V923= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV53263244; called by muse, mutect2, varscan2
